Somatic mutation profile of tumor specimen 0DSJY6 from CCDI case PBCIAW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.9 years (1,430 days).
Specimen 0DSJY6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7121648-7e22-46b1-bf1a-107a319fb719.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSJYJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fbbecee-8dd7-4f7a-82a1-e196224bc41b

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WNK3 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs782042256, COSV100672415; called by muse, mutect2, varscan2
- MOGS | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ASB13 | c.-13G>A | 5'UTR (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- GABRD | c.553+67G>A | Intron (SNP) | VAF 15/122 reads (12%) | catalogued as rs559125904; called by muse, mutect2, varscan2
